Somatic mutation profile of tumor specimen ALCH-B1TZ-TTP1-A (aliquot ALCH-B1TZ-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1TZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 83.3 years (30,432 days).
Specimen ALCH-B1TZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b58dd704-121a-4ddb-aada-16b6f84f1e51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1TZ-NB1-A (Blood Derived Normal), aliquot ALCH-B1TZ-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89469de2-3d42-4a03-8f36-fbda1ed51ea7

The open-access MAF lists 215 somatic variants for this specimen: 148 protein-altering or splice-affecting, 47 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 47, Nonsense Mutation 12, Intron 12, Splice Region 3, Splice Site 2, 3'UTR 2, 5'Flank 2, RNA 2, 3'Flank 1, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.715A>G p.N239D | Missense Mutation (SNP) | VAF 17/287 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs876660807, COSV52664075, COSV52685174, COSV52979974, COSV53345856; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- A1CF | c.509C>G p.P170R | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV50991082, COSV99255611; called by muse, mutect2
- A1CF | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50988861; called by muse, mutect2
- ADCY8 | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs373225005, COSV53900962; called by muse, mutect2
- ALOX5AP | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 22/244 reads (9%) | catalogued as COSV66857950; called by muse, mutect2
- BUB1 | c.1416G>T p.M472I | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57061284, COSV57062328; called by muse, mutect2
- CCDC14 | c.1900C>T p.H634Y (on ENST00000488653; = p.H586Y on NM_022757.5) | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs953430141, COSV59942931; called by muse, mutect2
- CDH10 | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as COSV52593859, COSV52596113; called by muse, mutect2, varscan2
- CEP170B | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1257081434; called by muse, mutect2
- CERS3 | c.493G>T p.V165F | Missense Mutation (SNP) | VAF 13/248 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs1567648942; called by muse, mutect2
- CSDE1 | c.563G>T p.G188V (on ENST00000358528 / NM_001007553.3; = p.G157V on NM_007158.6) | Missense Mutation (SNP) | VAF 24/542 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV54749919; called by muse, mutect2
- CUL3 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 9/200 reads (5%) | catalogued as COSV52367038; called by muse, mutect2
- DNASE1L3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59156452, COSV59156914; called by muse, mutect2
- EXO1 | c.2406A>T p.K802N (on ENST00000348581 / NM_001319224.1; = p.X802_splice on NM_003686.4) | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV62219924; called by muse, mutect2
- EYS | c.1243C>A p.L415I | Missense Mutation (SNP) | VAF 23/405 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.53); catalogued as rs1387469389; called by muse, mutect2
- FBXL8 | c.311G>C p.R104P | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV50456540; called by muse, mutect2, varscan2
- GCC2 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 12/311 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV59173756, COSV59177754; called by muse, mutect2
- GOLGA6L2 | c.6G>T p.W2C | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61481338; called by muse, mutect2
- LILRB2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as rs1407009553, COSV100078930, COSV58743817; called by muse, mutect2
- LRCH3 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); catalogued as rs778870012; called by muse, mutect2
- MOXD1 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1320822814; called by muse, mutect2
- NBAS | c.3687G>T p.K1229N | Missense Mutation (SNP) | VAF 12/406 reads (3%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.851); catalogued as COSV99871563; called by muse, mutect2
- OR4C6 | c.798C>A p.D266E | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.521); catalogued as rs776313625; called by muse, mutect2
- OR5D13 | c.694T>A p.S232T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.458); catalogued as rs1400406694; called by muse, mutect2
- OR6N2 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100210585; called by muse, mutect2
- PBDC1 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 8/127 reads (6%) | catalogued as COSV100972772; called by muse, mutect2
- PGK2 | c.393G>C p.K131N | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV59164213; called by muse, mutect2
- PRPS1 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 30/516 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV65054441; called by muse, mutect2
- RB1 | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.974); catalogued as CM1312466, COSV57321229; called by muse, mutect2
- RFXANK | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.503); catalogued as rs757517948, COSV57393806; ClinVar: uncertain significance; called by muse, mutect2
- RNFT2 | c.24+7C>T | Splice Region (SNP) | VAF 14/250 reads (6%) | catalogued as rs1299115878; called by muse, mutect2
- RYR2 | c.7958C>A p.S2653Y | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1553269691; ClinVar: uncertain significance; called by muse, mutect2
- SCN10A | c.2473G>T p.E825* | Nonsense Mutation (SNP) | VAF 8/145 reads (6%) | catalogued as COSV71860926; called by muse, mutect2
- SLC7A14 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.535); catalogued as COSV99200525; called by muse, mutect2
- ST6GALNAC1 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | PolyPhen benign (0.019); catalogued as rs762648078, COSV50077100; called by muse, mutect2, varscan2
- SYT10 | c.1323G>T p.E441D | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.146); catalogued as COSV57346803, COSV99951983; called by muse, mutect2
- TBC1D21 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/280 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.577); catalogued as COSV55996709; called by muse, mutect2
- TGFBR3 | c.1946G>A p.R649K | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.213); catalogued as rs775607589, COSV53031768; called by muse, mutect2
- TLR9 | c.2774C>T p.A925V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.538); catalogued as rs200791761; called by muse, mutect2, varscan2
- TSC2 | c.1840-4A>G | Splice Region (SNP) | VAF 14/237 reads (6%) | catalogued as rs1057523736; ClinVar: likely benign; called by muse, mutect2
- USH2A | c.4571G>T p.G1524V | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56417661; called by muse, mutect2
- USH2A | c.4570G>T p.G1524* | Nonsense Mutation (SNP) | VAF 14/232 reads (6%) | catalogued as COSV56434483, COSV56449165; called by muse, mutect2
- WDR17 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99707169, COSV99708334; called by muse, mutect2
- YIPF4 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs375039400; called by muse, mutect2
- ZNF711 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 24/335 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.152); catalogued as rs1363391373; called by muse, mutect2
- ABCA13 | c.8326G>C p.E2776Q | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by muse, mutect2
- ABCB7 | c.500G>T p.S167I (on ENST00000373394 / NM_001271696.3; = p.S168I on NM_004299.6) | Missense Mutation (SNP) | VAF 21/482 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.062); called by muse, mutect2
- ABCD3 | c.1903-1G>T p.X635_splice | Splice Site (SNP) | VAF 26/496 reads (5%) | called by muse, mutect2
- APOB | c.9291G>T p.K3097N | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2
- APOB | c.3244G>T p.E1082* | Nonsense Mutation (SNP) | VAF 17/302 reads (6%) | called by muse, mutect2
- ARHGEF38 | c.2119G>T p.V707F | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.063); called by muse, mutect2
- ARMC4 | c.1719G>T p.R573S | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2
- ATP7A | c.3712C>G p.L1238V | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2
- BIRC6 | c.6223C>T p.R2075W | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BMX | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 11/215 reads (5%) | called by muse, mutect2
- BNC1 | c.161G>C p.R54P | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C10orf71 | c.2157G>T p.M719I | Missense Mutation (SNP) | VAF 18/365 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2
- C1GALT1 | c.884T>C p.V295A | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA1H | c.3320G>T p.S1107I | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2
- CAPS2 | c.299G>T p.W100L | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2
- CATSPER2 | c.916G>T p.V306F | Missense Mutation (SNP) | VAF 27/446 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.124); called by muse, mutect2
- CCDC168 | c.1370A>T p.N457I | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2
- CCDC88B | c.2062G>T p.G688W | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2
- CDH9 | c.2074G>T p.V692L | Missense Mutation (SNP) | VAF 47/377 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- CEP97 | c.2293A>T p.N765Y | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CFAP58 | c.183G>C p.M61I | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.122); called by muse, mutect2
- COG4 | c.409T>G p.L137V | Missense Mutation (SNP) | VAF 30/480 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- COL4A3 | c.2390C>A p.P797H | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- CRIM1 | c.794A>T p.Q265L | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.053); called by muse, mutect2
- DACH1 | c.2186A>G p.E729G (on ENST00000619232 / NM_001366712.1; = p.E475G on NM_004392.6) | Missense Mutation (SNP) | VAF 23/487 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.298); called by muse, mutect2
- DBF4B | c.257G>T p.S86I | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2
- DIRAS2 | c.469A>C p.N157H | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- DSCAML1 | c.2602C>G p.L868V (on ENST00000321322; = p.L808V on NM_020693.4) | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.785); called by muse, mutect2
- ECH1 | c.830T>G p.V277G | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.946); called by muse, mutect2
- ELAVL4 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2
- EML5 | c.2014G>C p.A672P | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.87); called by muse, mutect2
- EVC | c.2595G>C p.Q865H | Missense Mutation (SNP) | VAF 22/407 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- FAT3 | c.5690A>T p.Y1897F | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- FBXO47 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 14/289 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- FCRLA | c.892G>T p.A298S (on ENST00000367959; = p.A275S on NM_032738.4) | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.194); called by muse, mutect2
- FGD1 | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- GABRG2 | c.19T>G p.W7G | Missense Mutation (SNP) | VAF 32/572 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); called by muse, mutect2
- GJB1 | c.554C>A p.T185N | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GRIA3 | c.521T>A p.L174H | Missense Mutation (SNP) | VAF 17/335 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GRIK1 | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.994); called by muse, mutect2
- HDC | c.1874T>G p.L625R | Missense Mutation (SNP) | VAF 38/583 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- HEPACAM2 | c.632A>T p.K211M (on ENST00000394468 / NM_001039372.4; = p.K199M on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/357 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IER3 | c.210G>C p.V70= | Splice Region (SNP) | VAF 13/234 reads (6%) | called by muse, mutect2
- IGKV2-24 | c.194C>G p.P65R | Missense Mutation (SNP) | VAF 20/474 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- ITGAD | c.2874C>A p.S958R | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.159); called by muse, mutect2
- KDR | c.3208A>G p.K1070E | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLF7 | c.644A>G p.K215R | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.162); called by muse, mutect2
- KLHL4 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 25/349 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.026); called by muse, mutect2
- KRT33A | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); called by muse, mutect2
- KRTAP10-1 | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 13/375 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- LAMP5 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRRIQ3 | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 13/352 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.376); called by muse, mutect2
- MGAM2 | c.3970C>A p.H1324N | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.059); called by muse, mutect2
- MTMR14 | c.1389G>T p.E463D | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2
- MTUS2 | c.1969C>T p.Q657* | Nonsense Mutation (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- MUC16 | c.16465C>A p.L5489M | Missense Mutation (SNP) | VAF 13/270 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); called by muse, mutect2
- MYOM2 | c.4363C>G p.L1455V | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.012); called by muse, mutect2
- NBAS | c.3688A>T p.I1230F | Missense Mutation (SNP) | VAF 12/408 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- NLGN1 | c.1650-1G>T p.X550_splice | Splice Site (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
- NPHP3 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- NUP205 | c.1772A>T p.Q591L | Missense Mutation (SNP) | VAF 27/393 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.493); called by muse, mutect2
- OR1F1 | c.621G>T p.M207I | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.013); called by muse, mutect2
- OR4A47 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- OR4A47 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.393); called by muse, mutect2
- OR51A7 | c.410C>A p.T137N | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.424); called by muse, mutect2
- PBRM1 | c.2666C>A p.P889Q | Missense Mutation (SNP) | VAF 34/498 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- PCDH11X | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 36/610 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2
- PDGFRA | c.740G>T p.W247L | Missense Mutation (SNP) | VAF 24/455 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDPR | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 13/396 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0.038); called by muse, mutect2
- PER3 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- PLEC | c.9425G>T p.R3142L (on ENST00000322810 / NM_201380.4; = p.R3032L on NM_000445.5) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PNLIPRP3 | c.476C>A p.P159H | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, mutect2
- PPP4R3C | c.2038G>C p.E680Q | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKCE | c.2095G>C p.D699H | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PSCA | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2
- PTCHD4 | c.1556T>A p.I519K | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- RAB33A | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RNF17 | c.2032A>C p.T678P | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.653); called by muse, mutect2
- RYR2 | c.8737G>T p.D2913Y | Missense Mutation (SNP) | VAF 16/309 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SAAL1 | c.134A>T p.Q45L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.167); called by muse, varscan2
- SCNM1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2
- SHANK1 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 19/284 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHOX2 | c.904G>A p.A302T (on ENST00000441443 / NM_006884.3; = p.A326T on NM_003030.4) | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SIGLEC1 | c.599A>T p.E200V | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.074); called by muse, mutect2
- SLX4 | c.1197A>T p.R399S | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2
- SORCS1 | c.3495G>T p.Q1165H | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- SPATA31A6 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.139); called by muse, mutect2
- STAG2 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 18/368 reads (5%) | called by muse, mutect2
- SYTL5 | c.1039T>A p.S347T | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2
- TAOK3 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 15/293 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- TNNT2 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 12/275 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- TPP1 | c.669C>A p.N223K | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- TRHR | c.905T>A p.L302* | Nonsense Mutation (SNP) | VAF 39/506 reads (8%) | called by muse, mutect2
- TRIM49C | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- TTC17 | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.411); called by muse, mutect2
- UGGT2 | c.1942G>T p.D648Y | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2
- UNC5D | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.241); called by muse, mutect2
- USP27X | c.1192G>T p.A398S | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.264); called by muse, mutect2
- XDH | c.2811G>T p.M937I | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- ZBTB44 | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZEB2 | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- ZMYM3 | c.1582T>A p.C528S | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF99 | c.1537G>T p.E513* | Nonsense Mutation (SNP) | VAF 22/474 reads (5%) | called by muse, mutect2
- ACTN4 | c.2502C>T p.F834= | Silent (SNP) | VAF 17/273 reads (6%) | catalogued as rs763804143; called by muse, mutect2
- ADD2 | c.1551C>T p.S517= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- ADGRL4 | c.198T>C p.T66= | Silent (SNP) | VAF 9/187 reads (5%) | catalogued as rs1402388713; called by muse, mutect2
- ANK1 | c.15G>T p.V5= | Silent (SNP) | VAF 11/206 reads (5%) | catalogued as COSV55888723; called by muse, mutect2
- ANKRD2 | c.354G>T p.L118= | Silent (SNP) | VAF 11/175 reads (6%) | called by muse, mutect2
- CACNA1F | c.4257C>T p.A1419= | Silent (SNP) | VAF 20/430 reads (5%) | catalogued as COSV100544412; called by muse, mutect2
- CYBB | c.924C>T p.I308= | Silent (SNP) | VAF 17/302 reads (6%) | catalogued as rs782150170; called by muse, mutect2
- DDR2 | c.2322G>T p.G774= | Silent (SNP) | VAF 54/716 reads (8%) | catalogued as COSV63370614; called by muse, mutect2
- DUSP19 | c.153G>T p.G51= | Silent (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- DVL3 | c.399A>G p.T133= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- EDNRB | c.672C>T p.N224= (on ENST00000377211 / NM_001201397.1; = p.N134= on NM_000115.5) | Silent (SNP) | VAF 12/231 reads (5%) | catalogued as COSV57524555; called by muse, mutect2
- ELK1 | c.126G>T p.V42= | Silent (SNP) | VAF 10/225 reads (4%) | called by muse, mutect2
- FCER2 | c.699C>A p.I233= | Silent (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- GEN1 | c.267G>A p.R89= | Silent (SNP) | VAF 22/386 reads (6%) | called by muse, mutect2
- GPR65 | c.159C>T p.L53= | Silent (SNP) | VAF 15/275 reads (5%) | called by muse, mutect2
- GRIK1 | c.582C>G p.S194= | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- GRM8 | c.2697A>T p.T899= | Silent (SNP) | VAF 19/276 reads (7%) | called by muse, mutect2
- H2BC8 | c.66G>C p.A22= | Silent (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2
- HSP90AA1 | c.1494C>T p.T498= | Silent (SNP) | VAF 14/319 reads (4%) | called by muse, mutect2
- KCNV1 | c.202C>T p.L68= | Silent (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- LAYN | c.243C>A p.I81= (on ENST00000375615 / NM_001258390.1; = p.I73= on NM_178834.5) | Silent (SNP) | VAF 26/452 reads (6%) | catalogued as COSV65105666; called by muse, mutect2
- LRP2 | c.12537G>C p.L4179= | Silent (SNP) | VAF 38/410 reads (9%) | called by muse, mutect2
- MAGEE1 | c.2244G>A p.K748= | Silent (SNP) | VAF 11/298 reads (4%) | called by muse, mutect2
- MAMLD1 | c.2025G>C p.V675= | Silent (SNP) | VAF 14/442 reads (3%) | called by muse, mutect2
- MICOS13 | c.222A>C p.P74= | Silent (SNP) | VAF 9/170 reads (5%) | called by muse, mutect2
- MYH13 | c.5757C>T p.S1919= | Silent (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- OR2M5 | c.375C>A p.A125= | Silent (SNP) | VAF 32/397 reads (8%) | called by muse, mutect2
- OR8G1 | c.357G>A p.A119= | Silent (SNP) | VAF 22/309 reads (7%) | catalogued as rs769418625, COSV58384156; called by muse, mutect2
- OR8H1 | c.775T>C p.L259= | Silent (SNP) | VAF 8/129 reads (6%) | called by muse, mutect2
- PCDHGB1 | c.1248C>T p.V416= | Silent (SNP) | VAF 13/164 reads (8%) | called by muse, mutect2
- PHF3 | c.5043G>T p.L1681= | Silent (SNP) | VAF 16/209 reads (8%) | called by muse, mutect2
- PIGA | c.1302C>T p.F434= | Silent (SNP) | VAF 25/407 reads (6%) | called by muse, mutect2
- PITPNM3 | c.183C>T p.L61= | Silent (SNP) | VAF 24/411 reads (6%) | catalogued as rs751095976, COSV52597954; called by muse, mutect2
- POTEE | c.963C>A p.V321= | Silent (SNP) | VAF 24/762 reads (3%) | called by muse, mutect2
- PUS7L | c.1548C>T p.I516= | Silent (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- QSER1 | c.3277C>T p.L1093= (on ENST00000399302; = p.L1222= on NM_001076786.3) | Silent (SNP) | VAF 8/111 reads (7%) | called by muse, mutect2
- RIF1 | c.5979A>G p.Q1993= | Silent (SNP) | VAF 35/325 reads (11%) | catalogued as rs1214171599; called by muse, mutect2, varscan2
- RYR2 | c.6979A>C p.R2327= | Silent (SNP) | VAF 24/390 reads (6%) | called by muse, mutect2
- SLC7A3 | c.268C>A p.R90= | Silent (SNP) | VAF 20/302 reads (7%) | called by muse, mutect2
- SLCO1C1 | c.231T>A p.P77= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- SMS | c.252A>G p.E84= | Silent (SNP) | VAF 24/317 reads (8%) | called by muse, mutect2
- TAB3 | c.1377A>T p.V459= | Silent (SNP) | VAF 14/191 reads (7%) | called by muse, mutect2
- TNR | c.1416A>T p.T472= | Silent (SNP) | VAF 16/338 reads (5%) | catalogued as COSV54872661; called by muse, mutect2
- TTBK1 | c.3681C>A p.P1227= | Silent (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- USP33 | c.1710A>G p.Q570= | Silent (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- USP48 | c.327C>G p.L109= | Silent (SNP) | VAF 12/185 reads (6%) | catalogued as rs1217131180; called by muse, mutect2
- ZNF467 | c.474G>A p.K158= | Silent (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- AC013717.1 | c.1134+25779G>C | Intron (SNP) | VAF 15/265 reads (6%) | called by muse, mutect2
- AC107023.1 | n.25+7711C>A | Intron (SNP) | VAF 14/265 reads (5%) | called by muse, mutect2
- AKAP7 | c.*878A>C | 3'UTR (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2
- AL669831.6 | chr1:786129 T>C | 3'Flank (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- DBF4B | c.468+24G>T | Intron (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- DNAI2 | c.1347+85C>A | Intron (SNP) | VAF 20/330 reads (6%) | called by muse, mutect2
- DOCK2 | c.3072+1858C>A | Intron (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- GALNT14 | c.129+12713C>A | Intron (SNP) | VAF 13/195 reads (7%) | called by muse, mutect2
- LIPT2 | chr11:74497648 A>C | 5'Flank (SNP) | VAF 13/178 reads (7%) | catalogued as rs1321551665; called by muse, mutect2
- NLGN3 | c.518-21C>A | Intron (SNP) | VAF 30/432 reads (7%) | called by muse, mutect2
- OR51A7 | c.*48G>T | 3'UTR (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
- PATE2 | c.-15G>A | 5'UTR (SNP) | VAF 17/161 reads (11%) | called by muse, mutect2, varscan2
- RPS6KA6 | c.81+1689T>C | Intron (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- SPATA31C2 | n.1996T>C | RNA (SNP) | VAF 26/444 reads (6%) | called by muse, mutect2
- TIMP1 | c.329-98C>T | Intron (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- TSPAN7 | c.82-43152G>A | Intron (SNP) | VAF 17/225 reads (8%) | called by muse, mutect2
- WASF4P | n.1363C>A | RNA (SNP) | VAF 26/334 reads (8%) | called by muse, mutect2
- WT1 | c.965+1010C>A | Intron (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- ZIC4 | c.688+1941G>C | Intron (SNP) | VAF 30/259 reads (12%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149776480 G>T | 5'Flank (SNP) | VAF 14/142 reads (10%) | catalogued as rs369875598; called by muse, mutect2
